Somatic mutation profile of tumor specimen TCGA-W7-A93O-01A (aliquot TCGA-W7-A93O-01A-31D-A46P-09) from TCGA case TCGA-W7-A93O, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3.
Specimen TCGA-W7-A93O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81a2b4f4-03a7-4a04-8a70-d890d2e3c68d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W7-A93O-11A (Solid Tissue Normal), aliquot TCGA-W7-A93O-11A-11D-A46P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8b95f89-437a-47a3-910e-578a681b43ce

The open-access MAF lists 116 somatic variants for this specimen: 81 protein-altering or splice-affecting, 31 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 31, Nonsense Mutation 9, Frame Shift Ins 3, Frame Shift Del 2, Splice Site 2, Intron 2, RNA 1, In Frame Del 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA1 | c.5551C>T p.R1851* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as rs1262486352, CM020397; called by muse, mutect2, varscan2
- AFF3 | c.670C>A p.P224T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.106); catalogued as COSV57857076; called by muse, mutect2
- ART3 | c.33G>A p.M11I | Missense Mutation (SNP) | VAF 39/65 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV61915161; called by muse, mutect2, varscan2
- CLASP1 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs753925339; called by muse, mutect2, varscan2
- CLEC2B | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.389); catalogued as rs746081758, COSV57310171; called by muse, mutect2, varscan2
- COL11A1 | c.4613C>A p.P1538Q | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1474325280; called by muse, mutect2, varscan2
- DTNA | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as COSV52015758; called by muse, mutect2, varscan2
- DYNC1LI2 | c.479T>C p.I160T | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV104382977, COSV50756314; called by muse, mutect2, varscan2
- ESCO2 | c.1339T>C p.F447L | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs1341322000; called by muse, mutect2, varscan2
- FERD3L | c.46T>G p.F16V | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV51761976, COSV51764624; called by muse, mutect2, varscan2
- FSCN1 | c.1466C>T p.S489L | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as rs1472964717; called by muse, mutect2, varscan2
- FZD9 | c.983C>T p.S328L | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60671455; called by muse, mutect2, varscan2
- GABRA3 | c.780A>C p.G260= | Splice Region (SNP) | VAF 18/88 reads (20%) | catalogued as COSV64795489; called by muse, mutect2, varscan2
- GLIS1 | c.1415C>T p.P472L | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs767466845, COSV100390710; called by muse, mutect2, varscan2
- H1-6 | c.150G>T p.E50D | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.155); catalogued as rs747601733, COSV58091389; called by muse, mutect2, varscan2
- KCNQ2 | c.2138C>T p.P713L (on ENST00000359125 / NM_172107.4; = p.P685L on NM_004518.6) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.787); catalogued as rs750333438, COSV60545260; called by muse, mutect2, varscan2
- KDR | c.2935G>A p.E979K | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.935); catalogued as COSV99818295; called by muse, mutect2, varscan2
- KIF26B | c.502C>T p.Q168* | Nonsense Mutation (SNP) | VAF 6/47 reads (13%) | catalogued as COSV68572365; called by muse, mutect2, varscan2
- LRIT2 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as rs139238795; called by muse, mutect2, varscan2
- MAN1A2 | c.1921C>T p.R641* | Nonsense Mutation (SNP) | VAF 23/50 reads (46%) | catalogued as rs748904688, COSV62977205; called by muse, mutect2, varscan2
- MED16 | c.183G>A p.M61I | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs1444129599; called by muse, mutect2, varscan2
- MMP2 | c.1388C>G p.P463R | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54602914; called by muse, mutect2, varscan2
- PKHD1 | c.3526G>A p.V1176I | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.2); catalogued as rs565045703; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RASGRP4 | c.61C>T p.R21* | Nonsense Mutation (SNP) | VAF 66/152 reads (43%) | catalogued as rs766578361, COSV99498370; called by muse, mutect2, varscan2
- SHANK1 | c.1592C>T p.T531M | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as rs756769589, COSV53249331; called by muse, mutect2, varscan2
- SLC28A3 | c.1025C>T p.T342M | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs375012676; called by muse, mutect2, varscan2
- SORCS1 | c.2641G>A p.V881I | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as rs746041232, COSV53854540; called by muse, mutect2, varscan2
- SYCP1 | c.2886G>T p.M962I | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV65698044, COSV65701673; called by muse, mutect2, varscan2
- SYT12 | c.1231C>T p.P411S | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67354852; called by muse, mutect2, varscan2
- SYTL3 | c.144G>A p.W48* | Nonsense Mutation (SNP) | VAF 9/53 reads (17%) | catalogued as COSV51912824; called by mutect2, varscan2
- TSPYL2 | c.385G>C p.E129Q | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.3); catalogued as COSV60234633; called by muse, varscan2
- TUBAL3 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.687); catalogued as rs374684494; called by muse, mutect2, varscan2
- TULP4 | c.4136G>A p.R1379K | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.98); catalogued as COSV65580856; called by muse, mutect2, varscan2
- VPS13D | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as rs143532013; called by muse, mutect2, varscan2
- ZNF345 | c.199T>C p.C67R | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs755901097; called by muse, mutect2, varscan2
- ZNF789 | c.773G>C p.R258T | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100507876, COSV58874390; called by muse, mutect2, varscan2
- ANKRD1 | c.789C>A p.N263K | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- AR | c.938A>T p.K313M | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ATP7A | c.3828A>C p.E1276D | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC7 | c.919_921del p.Q307del | In Frame Del (DEL) | VAF 22/89 reads (25%) | called by mutect2, pindel, varscan2
- CDH12 | c.792C>A p.D264E | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- CFAP20DC | c.701G>T p.R234I (on ENST00000482387 / NM_001351530.2; = p.R109I on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- CFAP61 | c.1388C>G p.S463C | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- CHD5 | c.5457C>A p.N1819K | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.102); called by mutect2, varscan2
- CHD5 | c.5454_5455dup p.N1819Tfs*44 | Frame Shift Ins (INS) | VAF 21/121 reads (17%) | called by mutect2, pindel, varscan2
- CRAT | c.27+1G>T p.X9_splice | Splice Site (SNP) | VAF 5/10 reads (50%) | called by muse, mutect2, varscan2
- EXOC6B | c.1224del p.F408Lfs*12 | Frame Shift Del (DEL) | VAF 13/62 reads (21%) | called by pindel, varscan2
- FCGBP | c.5579C>A p.S1860Y | Missense Mutation (SNP) | VAF 11/230 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); called by muse, mutect2
- FNDC3B | c.3603C>G p.F1201L | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- FSIP1 | c.1291_1292insC p.K431Tfs*5 | Frame Shift Ins (INS) | VAF 11/85 reads (13%) | called by mutect2, pindel, varscan2
- GNAQ | c.1039A>G p.T347A | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- GRIA3 | c.830A>T p.N277I | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- KLK4 | c.688C>T p.Q230* | Nonsense Mutation (SNP) | VAF 53/133 reads (40%) | called by muse, mutect2, varscan2
- LRRC1 | c.1417-1G>T p.X473_splice | Splice Site (SNP) | VAF 14/64 reads (22%) | called by muse, mutect2, varscan2
- MCM8 | c.1915G>T p.E639* | Nonsense Mutation (SNP) | VAF 18/77 reads (23%) | called by muse, mutect2, varscan2
- MUC16 | c.15527A>G p.E5176G | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OPHN1 | c.2270C>T p.P757L | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2T33 | c.505G>T p.A169S | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2
- OSBPL11 | c.1626G>A p.M542I | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PCDHAC2 | c.1241G>T p.G414V | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- PLK2 | c.1161_1162del p.R387Sfs*3 | Frame Shift Del (DEL) | VAF 35/103 reads (34%) | called by pindel, varscan2
- PSAT1 | c.1105C>T p.Q369* (on ENST00000376588 / NM_058179.4; = p.Q323* on NM_021154.5) | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | called by muse, mutect2, varscan2
- RAD54B | c.50A>T p.K17I | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- RSBN1L | c.1774G>T p.A592S | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2
- SESTD1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SLC16A7 | c.1334C>A p.T445N | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- SMG1 | c.5001G>C p.E1667D | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SNCAIP | c.2237A>G p.H746R | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- STX1B | c.623T>A p.I208N | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TBX10 | c.221T>A p.L74Q | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBX5 | c.1120C>A p.Q374K | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- TCP11L2 | c.1148T>G p.F383C | Missense Mutation (SNP) | VAF 67/109 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- TIAF1 | c.40C>T p.L14F | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- TP53 | c.1022_1023insA p.F341Lfs*6 | Frame Shift Ins (INS) | VAF 6/21 reads (29%) | called by mutect2, pindel, varscan2
- TRIM15 | c.499C>A p.H167N | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TTLL2 | c.636G>C p.K212N | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VCX3A | c.67T>G p.S23A | Missense Mutation (SNP) | VAF 22/345 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.198); called by muse, mutect2
- VN1R1 | c.1058C>G p.P353R | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by mutect2, varscan2
- ZBTB3 | c.716C>G p.S239* | Nonsense Mutation (SNP) | VAF 17/64 reads (27%) | called by muse, mutect2, varscan2
- ZNF16 | c.2018T>G p.I673S | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF521 | c.2195A>T p.D732V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ACTRT3 | c.684G>A p.K228= | Silent (SNP) | VAF 20/114 reads (18%) | called by muse, mutect2, varscan2
- AHNAK | c.6885G>T p.L2295= | Silent (SNP) | VAF 64/162 reads (40%) | called by muse, mutect2, varscan2
- AK8 | c.348G>A p.A116= | Silent (SNP) | VAF 23/38 reads (61%) | called by muse, mutect2, varscan2
- APEX2 | c.462C>T p.N154= | Silent (SNP) | VAF 44/162 reads (27%) | catalogued as rs1280019089; called by muse, mutect2, varscan2
- ATXN2 | c.1611G>A p.P537= (on ENST00000550104; = p.P377= on NM_002973.4) | Silent (SNP) | VAF 24/95 reads (25%) | catalogued as rs1315875576, COSV66482476; called by muse, mutect2, varscan2
- CACNA1G | c.1629C>T p.S543= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as rs757031741, COSV100661448; called by muse, mutect2, varscan2
- CD2AP | c.195T>C p.D65= | Silent (SNP) | VAF 26/137 reads (19%) | called by muse, mutect2, varscan2
- COL6A3 | c.7659C>T p.N2553= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs369335838; ClinVar: likely benign / uncertain significance; called by mutect2, varscan2
- COPA | c.1227A>G p.E409= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as rs1296008899; called by muse, mutect2, varscan2
- CSF2RA | c.768C>T p.D256= | Silent (SNP) | VAF 34/100 reads (34%) | catalogued as rs764658015; called by muse, mutect2, varscan2
- CYP4F2 | c.1230C>T p.D410= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as rs959057648; called by muse, mutect2, varscan2
- DNAH5 | c.7923T>G p.G2641= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs748304927; ClinVar: uncertain significance; called by muse, mutect2
- FBXO46 | c.123T>C p.G41= | Silent (SNP) | VAF 12/62 reads (19%) | called by muse, mutect2, varscan2
- FEM1B | c.54G>C p.L18= | Silent (SNP) | VAF 15/25 reads (60%) | called by muse, mutect2, varscan2
- FLRT1 | c.1452G>A p.L484= | Silent (SNP) | VAF 8/24 reads (33%) | called by mutect2, varscan2
- HOMER2 | c.747G>A p.L249= (on ENST00000304231 / NM_199330.3; = p.L238= on NM_004839.4) | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as rs1438225714; called by muse, mutect2, varscan2
- HTR3D | c.1110G>A p.P370= (on ENST00000382489 / NM_001163646.2; = p.P195= on NM_182537.3) | Silent (SNP) | VAF 41/73 reads (56%) | catalogued as rs955124637; called by muse, mutect2, varscan2
- KIF1C | c.1362G>T p.L454= | Silent (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- MYH2 | c.3441G>T p.R1147= | Silent (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
- PRXL2B | c.507C>T p.P169= (on ENST00000444521; = p.P121= on NM_152371.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 65/272 reads (24%) | catalogued as rs746297976; called by muse, mutect2, varscan2
- RELN | c.2373T>C p.P791= | Silent (SNP) | VAF 14/125 reads (11%) | called by muse, mutect2, varscan2
- RHOBTB1 | c.2064C>T p.F688= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as rs375325793, COSV100558490; called by muse, mutect2, varscan2
- SHE | c.975C>T p.Y325= | Silent (SNP) | VAF 39/100 reads (39%) | catalogued as rs140972919; called by muse, mutect2, varscan2
- SLCO6A1 | c.336C>T p.Y112= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV65815459; called by muse, mutect2, varscan2
- TLN1 | c.5865G>A p.R1955= | Silent (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- TMCO4 | c.1617C>A p.P539= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV53873368; called by muse, mutect2, varscan2
- TMEM130 | c.198C>T p.D66= | Silent (SNP) | VAF 29/125 reads (23%) | catalogued as rs782787823, COSV59558107; called by muse, mutect2, varscan2
- TMX2 | c.486C>T p.F162= | Silent (SNP) | VAF 39/131 reads (30%) | catalogued as rs774496524, COSV53553225; called by muse, mutect2, varscan2
- UAP1 | c.1023T>C p.V341= | Silent (SNP) | VAF 14/86 reads (16%) | called by muse, mutect2, varscan2
- ZNF521 | c.2196C>T p.D732= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV64123804; called by muse, mutect2, varscan2
- ZXDA | c.567C>T p.H189= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs144268469; called by muse, varscan2
- DCHS2 | n.1751T>A | RNA (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- INTS6L | c.*2G>T | 3'UTR (SNP) | VAF 26/86 reads (30%) | catalogued as COSV100878116; called by muse, mutect2, varscan2
- MTSS1 | c.1036-952G>A | Intron (SNP) | VAF 15/65 reads (23%) | catalogued as rs761386929, COSV100274949; called by muse, mutect2, varscan2
- PSG5 | c.431-2771G>A | Intron (SNP) | VAF 157/368 reads (43%) | called by muse, mutect2, varscan2
